Somatic mutation profile of tumor specimen TCGA-56-7221-01A (aliquot TCGA-56-7221-01A-11D-2042-08) from TCGA case TCGA-56-7221, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 79.0 years (28,873 days).
Specimen TCGA-56-7221-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 544abbd2-247d-47a7-8a63-fddc02646d6e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-56-7221-10A (Blood Derived Normal), aliquot TCGA-56-7221-10A-01D-2042-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9b80602d-9fc4-46a7-991e-804903cc31e2

The open-access MAF lists 314 somatic variants for this specimen: 228 protein-altering or splice-affecting, 83 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 199, Silent 83, Nonsense Mutation 16, Frame Shift Del 8, Splice Site 4, RNA 2, 3'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.329G>A p.W110* | Nonsense Mutation (SNP) | VAF 9/32 reads (28%) | hotspot (GDC flag); catalogued as rs1057519852, COSV58682976, COSV58690849; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1099C>T p.R367* (on ENST00000281708 / NM_001349798.2; = p.R287* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 46/96 reads (48%) | hotspot (GDC flag); catalogued as COSV55891887; called by muse, mutect2, varscan2
- FGFR3 | c.746C>G p.S249C | Missense Mutation (SNP) | VAF 14/30 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121913483, CM950470, COSV53390026; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NSD1 | c.1310C>G p.S437* | Nonsense Mutation (SNP) | VAF 16/39 reads (41%) | catalogued as rs121908067, CM020744, COSV100728420, COSV100728435; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.775G>T p.D259Y | Missense Mutation (SNP) | VAF 22/58 reads (38%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.073); catalogued as rs1567548929, COSV52662086, COSV52675732, COSV52773165, COSV52962390; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.548C>G p.S183* | Nonsense Mutation (SNP) | VAF 24/73 reads (33%) | catalogued as rs1555525970, COSV52662121, COSV52858115, COSV53050787, COSV53082360; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.7637C>G p.S2546C | Missense Mutation (SNP) | VAF 29/221 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); catalogued as COSV101446770; called by muse, mutect2, varscan2
- ABCA13 | c.8431C>T p.Q2811* | Nonsense Mutation (SNP) | VAF 16/102 reads (16%) | catalogued as COSV101446771, COSV101447101; called by muse, mutect2, varscan2
- ABCC10 | c.1717C>T p.L573F (on ENST00000372530 / NM_001198934.2; = p.L530F on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as rs769675618, COSV99766666; called by muse, mutect2, varscan2
- ADAMTS20 | c.18G>T p.W6C | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.16); catalogued as COSV101238909; called by muse, mutect2, varscan2
- ADGRL3 | c.830C>G p.T277R (on ENST00000506720 / NM_001322402.2; = p.T209R on NM_015236.6) | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101546857; called by muse, mutect2, varscan2
- ALPK1 | c.427A>G p.I143V | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as COSV99453056; called by muse, mutect2
- APOBEC3B | c.1063C>T p.P355S | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.373); catalogued as COSV100213641; called by muse, mutect2, varscan2
- AQP9 | c.545C>G p.S182C | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.886); catalogued as COSV99582602; called by muse, mutect2, varscan2
- ASCC3 | c.3634-1G>T p.X1212_splice | Splice Site (SNP) | VAF 17/68 reads (25%) | catalogued as COSV100225228; called by muse, mutect2, varscan2
- ASPM | c.500G>A p.R167K | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV99659538; called by muse, mutect2, varscan2
- ATAD2 | c.2038G>T p.E680* | Nonsense Mutation (SNP) | VAF 47/99 reads (47%) | catalogued as COSV54876867; called by muse, mutect2, varscan2
- ATG12 | c.41C>A p.S14* | Nonsense Mutation (SNP) | VAF 36/109 reads (33%) | catalogued as COSV99174623; called by muse, mutect2, varscan2
- BCR | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.212); catalogued as COSV100005972; called by muse, mutect2, varscan2
- BEST3 | c.691G>T p.G231W | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100437579; called by muse, mutect2, varscan2
- BFSP2 | c.655A>T p.T219S | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.019); catalogued as COSV100183551; called by muse, mutect2, varscan2
- BMERB1 | c.297del p.I100Sfs*17 | Frame Shift Del (DEL) | VAF 6/24 reads (25%) | catalogued as COSV55507275; called by mutect2, pindel, varscan2
- BOC | c.1847C>T p.T616M | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as rs145132372; called by muse, mutect2, varscan2
- BOP1 | c.1583G>A p.R528Q | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); catalogued as rs1338696892; called by muse, mutect2, varscan2
- BPIFB6 | c.597G>C p.Q199H | Missense Mutation (SNP) | VAF 59/230 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV100848483, COSV62755548, COSV62755935; called by muse, mutect2, varscan2
- BPIFC | c.850G>T p.E284* | Nonsense Mutation (SNP) | VAF 32/90 reads (36%) | catalogued as rs369618463, COSV100300744, COSV100301024; called by muse, mutect2, varscan2
- C14orf119 | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 51/177 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); catalogued as COSV99399059; called by muse, mutect2, varscan2
- C4BPA | c.800G>T p.C267F | Missense Mutation (SNP) | VAF 42/69 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100891147; called by muse, mutect2, varscan2
- C6 | c.675G>C p.R225S | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV99666509; called by muse, mutect2, varscan2
- C7 | c.136C>G p.Q46E | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV100495417; called by muse, mutect2, varscan2
- CACNB2 | c.659C>T p.P220L (on ENST00000324631 / NM_201596.3; = p.P165L on NM_000724.4) | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as rs1284954641, COSV56637069, COSV99993079; called by muse, mutect2, varscan2
- CACNG8 | c.353C>A p.A118E | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV104373919, COSV99554855; called by muse, mutect2, varscan2
- CARF | c.662G>C p.R221P | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100247491; called by muse, mutect2, varscan2
- CATSPER4 | c.553C>G p.L185V | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100128196; called by muse, mutect2, varscan2
- CBLN2 | c.97G>T p.G33W | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.322); catalogued as COSV99504150; called by mutect2, varscan2
- CCHCR1 | c.158C>T p.T53I | Missense Mutation (SNP) | VAF 41/157 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.134); catalogued as COSV66161271; called by muse, mutect2, varscan2
- CD3G | c.508C>G p.Q170E | Missense Mutation (SNP) | VAF 74/164 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV99416456; called by muse, mutect2, varscan2
- CD82 | c.470A>T p.N157I | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99907377; called by muse, mutect2, varscan2
- CDAN1 | c.1451G>C p.R484T | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV100661151, COSV62331342; called by muse, mutect2, varscan2
- CDH17 | c.1777C>A p.P593T | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50339639; called by muse, mutect2, varscan2
- CEP350 | c.2532G>C p.K844N | Missense Mutation (SNP) | VAF 60/201 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as COSV100854304; called by muse, varscan2
- CEP350 | c.2650G>A p.D884N | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.109); catalogued as COSV100854306; called by muse, varscan2
- CGB3 | c.15+1G>T p.X5_splice | Splice Site (SNP) | VAF 22/167 reads (13%) | catalogued as COSV100642188; called by muse, mutect2, varscan2
- CGB3 | c.15G>T p.Q5H | Missense Mutation (SNP) | VAF 23/167 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.85); catalogued as COSV100642189; called by muse, mutect2, varscan2
- CHST10 | c.777C>A p.H259Q | Missense Mutation (SNP) | VAF 29/212 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.42); catalogued as COSV99958694; called by muse, mutect2, varscan2
- CNGA1 | c.1782A>T p.K594N | Missense Mutation (SNP) | VAF 51/127 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.184); catalogued as COSV100652116; called by muse, mutect2, varscan2
- COG7 | c.1825G>C p.G609R | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100207359, COSV100207910; called by muse, mutect2, varscan2
- COL11A1 | c.7C>G p.P3A | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV100615149, COSV62180777; called by muse, mutect2, varscan2
- COL13A1 | c.1589G>T p.G530V (on ENST00000398978 / NM_001130103.2; = p.G473V on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100637284; called by muse, mutect2, varscan2
- COL1A2 | c.3332G>T p.G1111V | Missense Mutation (SNP) | VAF 58/127 reads (46%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.971); catalogued as HM060012, COSV51966994; called by muse, mutect2, varscan2
- COL1A2 | c.3950G>C p.C1317S | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99798599; called by muse, mutect2, varscan2
- CPNE1 | c.1185C>G p.I395M (on ENST00000352393; = p.I400M on NM_003915.5) | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100466991; called by muse, mutect2, varscan2
- CRB2 | c.1172G>A p.R391H | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs1474833179, COSV63503082; called by muse, mutect2, varscan2
- DIPK1B | c.287C>A p.S96* | Nonsense Mutation (SNP) | VAF 22/57 reads (39%) | catalogued as COSV100765434; called by muse, varscan2
- DLGAP5 | c.1809A>C p.E603D | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.761); catalogued as COSV99903645; called by muse, mutect2, varscan2
- DMBT1 | c.6601C>G p.R2201G (on ENST00000338354 / NM_001377530.1; = p.R1444G on NM_004406.3) | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.168); catalogued as COSV100352073; called by muse, mutect2, varscan2
- DNAH11 | c.2424C>A p.D808E | Missense Mutation (SNP) | VAF 56/99 reads (57%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.562); catalogued as COSV100177139; called by muse, mutect2, varscan2
- DSE | c.199A>G p.I67V | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.08); catalogued as rs762575961, COSV100528327; called by muse, mutect2, varscan2
- DST | c.9014A>T p.E3005V | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.299); catalogued as COSV99751132; called by muse, mutect2, varscan2
- DYNC1H1 | c.4127G>T p.R1376L | Missense Mutation (SNP) | VAF 58/188 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100794428, COSV100795112; called by muse, mutect2, varscan2
- DYSF | c.3887C>A p.S1296* | Nonsense Mutation (SNP) | VAF 15/64 reads (23%) | catalogued as COSV99244350; called by muse, mutect2, varscan2
- EBF1 | c.734G>T p.R245L | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); catalogued as COSV100565147; called by muse, mutect2, varscan2
- ERBB4 | c.3293C>A p.T1098N | Missense Mutation (SNP) | VAF 37/139 reads (27%) | SIFT tolerated (0.5); PolyPhen benign (0.025); catalogued as COSV100723529; called by muse, mutect2, varscan2
- ERCC2 | c.1534G>A p.E512K | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV101228694; called by muse, mutect2, varscan2
- ERICH3 | c.1936G>A p.D646N | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV100443409; called by muse, mutect2, varscan2
- EXD2 | c.1556G>C p.R519P (on ENST00000312994 / NM_001193362.1; = p.R394P on NM_018199.3) | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100473681; called by muse, mutect2
- FAM155A | c.593G>A p.G198E | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.494); catalogued as COSV101026794; called by muse, mutect2, varscan2
- FAM83H | c.53G>A p.G18E | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.433); catalogued as COSV101186920; called by muse, mutect2, varscan2
- FAM98A | c.898G>C p.G300R | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); catalogued as COSV99478985; called by muse, mutect2
- FBN2 | c.7491G>T p.Q2497H | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV99324988; called by muse, mutect2, varscan2
- FCRL1 | c.920C>T p.S307L | Missense Mutation (SNP) | VAF 40/67 reads (60%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV100839725; called by muse, mutect2, varscan2
- FEZ2 | c.707C>T p.S236F | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100001898; called by muse, mutect2, varscan2
- FNDC1 | c.3790C>G p.R1264G | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.029); catalogued as COSV99794936; called by muse, varscan2
- GDI1 | c.328G>A p.V110I | Missense Mutation (SNP) | VAF 43/63 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV100870650; called by muse, mutect2, varscan2
- GLP2R | c.1502G>A p.R501Q | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs114201794, COSV52328640; called by muse, mutect2
- GLS2 | c.1324G>T p.G442W | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100358193; called by muse, mutect2, varscan2
- GPC5 | c.260A>G p.Q87R | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as COSV100992827; called by muse, mutect2, varscan2
- GPR158 | c.2717T>A p.I906K | Missense Mutation (SNP) | VAF 67/206 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV100892883; called by muse, mutect2, varscan2
- GPX6 | c.20C>T p.A7V | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.009); catalogued as COSV100724757; called by muse, mutect2, varscan2
- GRIN2A | c.3482G>C p.G1161A | Missense Mutation (SNP) | VAF 49/195 reads (25%) | SIFT tolerated (0.8); PolyPhen benign (0.005); catalogued as COSV100408327; called by muse, mutect2, varscan2
- HIVEP3 | c.4489G>A p.E1497K | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); catalogued as COSV99911481; called by muse, mutect2, varscan2
- HIVEP3 | c.842G>A p.S281N | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99911486; called by muse, mutect2, varscan2
- IGLV2-33 | c.157C>A p.H53N | Missense Mutation (SNP) | VAF 104/447 reads (23%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.011); catalogued as rs1265583479; called by muse, mutect2, varscan2
- INO80 | c.304C>G p.L102V | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV100731537; called by muse, mutect2, varscan2
- IPO5 | c.1930G>C p.D644H | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99846990; called by muse, mutect2, varscan2
- IPO8 | c.313G>T p.D105Y | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as COSV99804738; called by muse, mutect2, varscan2
- IRX1 | c.624C>A p.S208R | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.329); catalogued as COSV100116237, COSV57361038; called by muse, mutect2, varscan2
- ITGA2B | c.2864T>C p.L955P | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as CM153664, COSV99288590; called by muse, mutect2, varscan2
- ITGA7 | c.1631C>T p.S544L (on ENST00000555728; = p.S500L on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs753481574, COSV57697799; called by muse, mutect2, varscan2
- ITGA8 | c.2975G>A p.S992N | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs368176501, COSV65232479; called by muse, mutect2, varscan2
- KCNC1 | c.710G>A p.R237Q | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs200015927, COSV56393147; called by muse, mutect2, varscan2
- KCNH7 | c.1951G>T p.G651C | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100034094; called by muse, mutect2, varscan2
- KCNV1 | c.404A>T p.Q135L | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99818868; called by muse, mutect2, varscan2
- KDR | c.3457T>A p.F1153I | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99816733; called by muse, mutect2, varscan2
- KIAA1109 | c.11831C>T p.P3944L | Missense Mutation (SNP) | VAF 54/93 reads (58%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.11); catalogued as rs1393862609, COSV99145806; called by muse, mutect2, varscan2
- KIF13A | c.947A>T p.N316I | Missense Mutation (SNP) | VAF 44/157 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99433881; called by muse, mutect2, varscan2
- KLHL1 | c.1132G>C p.A378P | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100917009, COSV100918079; called by muse, mutect2, varscan2
- KMT2D | c.7372C>T p.Q2458* | Nonsense Mutation (SNP) | VAF 34/105 reads (32%) | catalogued as COSV56408709, COSV56466296; called by muse, mutect2, varscan2
- KRBA1 | c.34G>T p.G12W | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99752199; called by muse, mutect2, varscan2
- KRT77 | c.515A>T p.N172I | Missense Mutation (SNP) | VAF 35/134 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100526920; called by muse, mutect2, varscan2
- LAMA5 | c.8374G>A p.G2792R | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.965); catalogued as COSV99438056; called by muse, mutect2, varscan2
- LRP12 | c.2464C>G p.R822G | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.68); catalogued as COSV99407202, COSV99408318; called by muse, mutect2, varscan2
- LRP1B | c.4180T>A p.W1394R | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101252627; called by muse, mutect2, varscan2
- LRRC37A | c.4976C>A p.A1659D | Missense Mutation (SNP) | VAF 33/168 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.099); catalogued as COSV100208099; called by muse, mutect2, varscan2
- LRRK2 | c.2417G>T p.G806V | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100109240, COSV54142106; called by muse, mutect2, varscan2
- LSM14B | c.94G>C p.D32H | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); catalogued as COSV99443748; called by muse, mutect2, varscan2
- LYZ | c.147G>T p.L49F | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV99720008; called by muse, varscan2
- MANEA | c.1165G>C p.A389P | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100721443, COSV100721465; called by muse, mutect2, varscan2
- MAP3K19 | c.2203G>C p.E735Q | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV100208064; called by muse, mutect2, varscan2
- MAPK15 | c.119C>T p.A40V | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1330750361, COSV100567689; called by muse, mutect2, varscan2
- MBTPS1 | c.1956G>T p.W652C | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100597357; called by muse, mutect2, varscan2
- MDN1 | c.8710G>C p.E2904Q | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.328); catalogued as COSV101020771; called by muse, mutect2, varscan2
- MED13L | c.6233G>T p.G2078V | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV99927882; called by muse, mutect2, varscan2
- MEF2B | c.725G>A p.G242E | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV99364303; called by muse, mutect2
- MGAT5 | c.16C>G p.P6A | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.12); catalogued as rs1371242665, COSV99924084, COSV99924482; called by muse, mutect2, varscan2
- MROH2B | c.4524C>A p.H1508Q | Missense Mutation (SNP) | VAF 41/81 reads (51%) | SIFT tolerated (0.37); PolyPhen benign (0.278); catalogued as COSV101270474; called by muse, mutect2, varscan2
- MS4A5 | c.162G>C p.Q54H | Missense Mutation (SNP) | VAF 21/144 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100280906; called by muse, mutect2, varscan2
- MYH1 | c.4022G>T p.R1341L | Missense Mutation (SNP) | VAF 34/139 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.131); catalogued as COSV56846986, COSV99874907; called by muse, mutect2, varscan2
- MYH9 | c.613-2A>G p.X205_splice | Splice Site (SNP) | VAF 32/62 reads (52%) | catalogued as COSV99337874; called by muse, mutect2, varscan2
- NAGA | c.1147G>T p.E383* | Nonsense Mutation (SNP) | VAF 88/191 reads (46%) | catalogued as COSV101124133, COSV67169806; called by muse, mutect2, varscan2
- NBL1 | c.247G>T p.D83Y | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99229335; called by muse, mutect2, varscan2
- NCBP2L | c.331A>G p.T111A | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.021); catalogued as COSV100966478; called by muse, mutect2, varscan2
- NDST3 | c.2188C>G p.R730G | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs536026389, COSV56612806, COSV99629604; called by muse, mutect2, varscan2
- NELL1 | c.592G>C p.G198R | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV100119030, COSV54302013; called by muse, mutect2, varscan2
- NMD3 | c.1444G>A p.E482K | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100664603; called by muse, mutect2, varscan2
- NOX4 | c.616T>A p.L206M | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT tolerated (0.16); PolyPhen benign (0.063); catalogued as COSV99629594; called by muse, mutect2, varscan2
- NPVF | c.430C>A p.L144M | Missense Mutation (SNP) | VAF 80/175 reads (46%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.527); catalogued as COSV99760153; called by muse, mutect2, varscan2
- NPY1R | c.439G>T p.G147W | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56714206; called by muse, mutect2, varscan2
- NR2F2 | c.641A>T p.E214V | Missense Mutation (SNP) | VAF 58/211 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101240918; called by muse, mutect2, varscan2
- NSMCE2 | c.556G>T p.G186C | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99786368; called by muse, mutect2
- NTNG2 | c.971G>T p.R324L | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV100647178, COSV100647253; called by muse, mutect2, varscan2
- NUTM2F | c.82C>G p.L28V | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.867); catalogued as COSV99479885; called by muse, mutect2, varscan2
- NXPH1 | c.812G>A p.G271E | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101339574; called by muse, mutect2
- OR1L4 | c.596T>C p.V199A | Missense Mutation (SNP) | VAF 29/366 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.307); catalogued as COSV99413778; called by muse, mutect2
- OR1L6 | c.704T>C p.V235A (on ENST00000373684; = p.V199A on NM_001004453.2) | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.519); catalogued as rs1284440960, COSV100490777; called by muse, mutect2, varscan2
- OR4A5 | c.367G>T p.A123S | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100156960; called by muse, mutect2, varscan2
- OR4C12 | c.737T>C p.V246A | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.734); catalogued as COSV100078267; called by muse, mutect2, varscan2
- OR4C15 | c.864A>T p.K288N (on ENST00000314644; = p.K234N on NM_001001920.2) | Missense Mutation (SNP) | VAF 31/155 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.331); catalogued as COSV100115371; called by muse, mutect2, varscan2
- OR4K2 | c.116T>C p.M39T | Missense Mutation (SNP) | VAF 73/316 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV100064068; called by muse, mutect2, varscan2
- OR4S2 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 50/155 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as COSV56745977, COSV56747868; called by muse, mutect2, varscan2
- OR9G1 | c.280G>T p.A94S | Missense Mutation (SNP) | VAF 22/152 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.176); catalogued as COSV100380234, COSV56451966; called by muse, mutect2, varscan2
- OR9Q1 | c.439G>T p.G147W | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100109367; called by muse, mutect2, varscan2
- OR9Q2 | c.333C>A p.D111E | Missense Mutation (SNP) | VAF 33/132 reads (25%) | SIFT tolerated (1); PolyPhen possibly damaging (0.633); catalogued as COSV100285316; called by muse, mutect2, varscan2
- OVCH1 | c.1973C>A p.T658K | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.017); catalogued as COSV100548233; called by muse, mutect2, varscan2
- P2RX2 | c.1100G>A p.G367E | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.003); catalogued as rs746677628, COSV57682720; called by muse, mutect2, varscan2
- PCDH15 | c.1173A>T p.Q391H | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.517); catalogued as COSV100215336; called by muse, mutect2, varscan2
- PCF11 | c.167C>G p.S56C | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.085); catalogued as rs1170881894, COSV100017776, COSV53529424; called by muse, mutect2, varscan2
- PCNT | c.1003G>C p.E335Q | Missense Mutation (SNP) | VAF 64/89 reads (72%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.745); catalogued as COSV100855047; called by muse, mutect2, varscan2
- PDE8B | c.1703C>G p.T568R | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53737308, COSV99366147; called by muse, mutect2, varscan2
- PI15 | c.292G>T p.A98S | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV99477797; called by muse, mutect2, varscan2
- PIK3C2B | c.2701C>T p.R901C | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs747728370, COSV100915982; called by muse, mutect2, varscan2
- PIK3CG | c.1328G>T p.S443I | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.048); catalogued as COSV100782532, COSV63255759; called by muse, mutect2, varscan2
- PKD2 | c.1055G>A p.S352N | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT tolerated (0.97); PolyPhen benign (0.003); catalogued as COSV99416835; called by muse, mutect2
- PKHD1 | c.3730G>T p.E1244* | Nonsense Mutation (SNP) | VAF 19/72 reads (26%) | catalogued as CM149115, COSV100581071, COSV61882957; called by muse, mutect2, varscan2
- PLEKHA4 | c.565G>T p.G189W | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV99612083; called by muse, mutect2, varscan2
- PLN | c.73C>A p.R25S | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.056); catalogued as CM152289, COSV100682504, COSV62645794; called by muse, mutect2, varscan2
- POLR3K | c.52C>T p.Q18* | Nonsense Mutation (SNP) | VAF 11/54 reads (20%) | catalogued as COSV51956683, COSV99244228; called by muse, mutect2, varscan2
- PPFIA3 | c.2442G>T p.K814N | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.175); catalogued as COSV100494692; called by muse, mutect2, varscan2
- PRDM9 | c.814C>T p.H272Y | Missense Mutation (SNP) | VAF 48/107 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99689794; called by muse, mutect2, varscan2
- PRX | c.3479T>C p.F1160S | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99396360; called by muse, mutect2
- PTGS1 | c.411C>G p.S137R | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV99792919; called by muse, mutect2, varscan2
- QSOX2 | c.380A>G p.N127S | Missense Mutation (SNP) | VAF 35/192 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100699687; called by muse, mutect2, varscan2
- RBM19 | c.305C>A p.P102H | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.518); catalogued as COSV55693024; called by muse, mutect2, varscan2
- RBM33 | c.982C>G p.Q328E | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.116); catalogued as COSV100265188; called by muse, mutect2, varscan2
- RFX7 | c.1005C>G p.I335M (on ENST00000559447 / NM_001368074.1; = p.I432M on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100428194, COSV57965895; called by muse, mutect2, varscan2
- RIMS2 | c.3682G>C p.D1228H | Missense Mutation (SNP) | VAF 68/142 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV51677027, COSV99160151; called by muse, mutect2, varscan2
- ROCK2 | c.2423A>G p.N808S | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated (0.85); PolyPhen benign (0.019); catalogued as rs1488092249, COSV100253992; called by muse, mutect2, varscan2
- RYR1 | c.13519G>T p.E4507* | Nonsense Mutation (SNP) | VAF 19/89 reads (21%) | catalogued as COSV100614475, COSV62107833; called by muse, mutect2, varscan2
- SEMA3A | c.2241G>T p.W747C | Missense Mutation (SNP) | VAF 62/147 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV99545295; called by muse, mutect2, varscan2
- SEMA3A | c.2240G>T p.W747L | Missense Mutation (SNP) | VAF 60/144 reads (42%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.459); catalogued as COSV99545301; called by muse, mutect2, varscan2
- SETD3 | c.134A>G p.K45R | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs529858722, COSV59285007; called by muse, mutect2, varscan2
- SH2D4A | c.706C>T p.L236= | Splice Region (SNP) | VAF 11/18 reads (61%) | catalogued as rs532388029, COSV99744252; called by muse, varscan2
- SLC13A5 | c.1585G>A p.G529R | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104395754, COSV99545685; called by muse, mutect2, varscan2
- SLC22A1 | c.1037G>C p.R346P | Missense Mutation (SNP) | VAF 32/126 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.763); catalogued as COSV100266400; called by muse, mutect2, varscan2
- SLC22A2 | c.250G>C p.A84P | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.049); catalogued as COSV100870919; called by muse, mutect2, varscan2
- SLC6A11 | c.331G>A p.G111R | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.833); catalogued as COSV99594023; called by muse, mutect2, varscan2
- SLCO1B1 | c.40C>A p.Q14K | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as COSV99917996; called by muse, mutect2, varscan2
- SOGA1 | c.2143G>A p.V715M | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as COSV99412791; called by muse, mutect2, varscan2
- SORCS3 | c.2996A>G p.Y999C | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.848); catalogued as COSV100863393; called by muse, mutect2, varscan2
- SOX10 | c.325A>C p.N109H | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100329655; called by muse, mutect2, varscan2
- SPANXN2 | c.301G>C p.D101H | Missense Mutation (SNP) | VAF 154/342 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV100979778, COSV65128228; called by muse, varscan2
- STAG3 | c.1906C>A p.H636N | Missense Mutation (SNP) | VAF 11/117 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100425632; called by muse, mutect2, varscan2
- STAT2 | c.2143G>A p.E715K | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.31); PolyPhen benign (0.055); catalogued as COSV99950615; called by muse, varscan2
- STK31 | c.371G>A p.R124Q | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.656); catalogued as rs754274194, COSV63455807; called by muse, mutect2, varscan2
- SYNE1 | c.25159G>T p.V8387L (on ENST00000367255 / NM_182961.4; = p.V8339L on NM_033071.3) | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs119103247, CM075028, COSV99553542; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SYNE1 | c.12551G>T p.S4184I (on ENST00000367255 / NM_182961.4; = p.S4113I on NM_033071.3) | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as COSV99553549; called by muse, mutect2, varscan2
- TENT4B | c.746T>C p.L249P (on ENST00000561678 / NM_001365323.2; = p.L234P on NM_001040284.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100665711; called by muse, mutect2, varscan2
- TJP1 | c.1324G>C p.D442H | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100632314; called by muse, mutect2, varscan2
- TLN2 | c.7009G>A p.D2337N | Missense Mutation (SNP) | VAF 35/132 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV100168005; called by muse, mutect2, varscan2
- TMC4 | c.1712T>G p.L571R (on ENST00000617472 / NM_001145303.3; = p.L565R on NM_144686.4) | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV99713705; called by muse, mutect2, varscan2
- TMEM132E | c.1763A>C p.E588A (on ENST00000321639; = p.E678A on NM_001304438.2) | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as COSV100395936, COSV58694911; called by muse, mutect2, varscan2
- TMEM255B | c.701C>A p.A234D | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.178); catalogued as COSV100944081; called by muse, mutect2, varscan2
- TRAPPC9 | c.1783C>G p.Q595E | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.817); catalogued as COSV101226683; called by muse, mutect2, varscan2
- TSSK2 | c.902C>G p.T301S | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT tolerated, low confidence (0.93); PolyPhen benign (0); catalogued as COSV99350622; called by muse, mutect2, varscan2
- TTC37 | c.1174A>G p.K392E | Missense Mutation (SNP) | VAF 104/194 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV100706364; called by muse, mutect2, varscan2
- TTN | c.67097C>A p.A22366D (on ENST00000591111; = p.A14942D on NM_003319.4) | Missense Mutation (SNP) | VAF 23/87 reads (26%) | PolyPhen probably damaging (0.967); catalogued as COSV100594407; called by muse, mutect2, varscan2
- TTN | c.61354G>C p.E20452Q (on ENST00000591111; = p.E13028Q on NM_003319.4) | Missense Mutation (SNP) | VAF 61/197 reads (31%) | PolyPhen probably damaging (0.997); catalogued as COSV100594409; called by muse, mutect2, varscan2
- TTN | c.60953C>A p.P20318H (on ENST00000591111; = p.P12894H on NM_003319.4) | Missense Mutation (SNP) | VAF 9/58 reads (16%) | PolyPhen probably damaging (0.999); catalogued as COSV100594412; called by muse, mutect2, varscan2
- TTN | c.46307C>A p.T15436N (on ENST00000591111; = p.T8012N on NM_003319.4) | Missense Mutation (SNP) | VAF 55/183 reads (30%) | PolyPhen benign (0.033); catalogued as COSV60191092; called by muse, mutect2, varscan2
- TTN | c.43613C>A p.P14538H (on ENST00000591111; = p.P7114H on NM_003319.4) | Missense Mutation (SNP) | VAF 56/239 reads (23%) | PolyPhen probably damaging (0.999); catalogued as COSV100594420; called by muse, mutect2, varscan2
- TUBB1 | c.784C>T p.R262C | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as rs146256655, COSV53886604; called by muse, mutect2, varscan2
- TVP23C | c.254G>T p.R85I | Missense Mutation (SNP) | VAF 28/155 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99846720; called by muse, mutect2, varscan2
- U2AF2 | c.317A>C p.Q106P | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100454089; called by muse, mutect2, varscan2
- UBE2J1 | c.758G>A p.R253Q | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs1172005945, COSV70561008; called by muse, mutect2, varscan2
- UBQLN3 | c.1696C>T p.L566F | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV100293354, COSV100293450; called by muse, mutect2, varscan2
- VPS13C | c.271G>T p.V91F | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1260567567, COSV99827145; called by muse, mutect2, varscan2
- VWA3B | c.3515C>A p.P1172Q | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.147); catalogued as COSV101417768; called by muse, mutect2, varscan2
- WDR45B | c.548C>A p.A183E | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101124407; called by muse, mutect2, varscan2
- XXYLT1 | c.901C>T p.R301C | Missense Mutation (SNP) | VAF 42/120 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs746241527, COSV100118075; called by muse, mutect2, varscan2
- ZFHX4 | c.6664G>T p.A2222S | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV99256260; called by muse, mutect2, varscan2
- ZFYVE1 | c.2272C>T p.R758C | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1348733527, COSV100606519; called by muse, mutect2, varscan2
- ZIC3 | c.694G>A p.A232T | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.986); catalogued as COSV99798333; called by muse, mutect2, varscan2
- ZNF257 | c.154C>A p.L52M | Missense Mutation (SNP) | VAF 24/154 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.583); catalogued as COSV101448017, COSV71310914; called by muse, mutect2, varscan2
- ZNF329 | c.1543C>T p.Q515* | Nonsense Mutation (SNP) | VAF 31/154 reads (20%) | catalogued as COSV100798668; called by muse, mutect2, varscan2
- ZNF462 | c.4799A>T p.H1600L | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99470791; called by muse, mutect2, varscan2
- ZNF827 | c.2835G>C p.K945N | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.864); catalogued as COSV101061154; called by muse, mutect2, varscan2
- ZNF98 | c.154G>T p.V52L | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100757294; called by muse, mutect2, varscan2
- AGBL5 | c.762_763del p.E255Dfs*4 | Frame Shift Del (DEL) | VAF 34/162 reads (21%) | called by mutect2, pindel, varscan2
- C2CD3 | c.695del p.S232* | Frame Shift Del (DEL) | VAF 123/294 reads (42%) | called by mutect2, pindel, varscan2
- CGB5 | c.15+1G>T p.X5_splice | Splice Site (SNP) | VAF 10/236 reads (4%) | called by muse, mutect2
- DCAF4L2 | c.208del p.A70Qfs*20 | Frame Shift Del (DEL) | VAF 10/102 reads (10%) | called by mutect2, varscan2
- IGF2R | c.4238del p.P1413Rfs*23 | Frame Shift Del (DEL) | VAF 16/57 reads (28%) | called by mutect2, pindel, varscan2
- IGHV1OR21-1 | c.274G>T p.D92Y | Missense Mutation (SNP) | VAF 42/649 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); called by muse, mutect2
- IGKV1D-42 | c.217G>T p.A73S | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- OR4D6 | c.455del p.G152Vfs*9 | Frame Shift Del (DEL) | VAF 52/167 reads (31%) | called by mutect2, pindel, varscan2
- PDE4B | c.1795del p.E599Kfs*47 | Frame Shift Del (DEL) | VAF 13/47 reads (28%) | called by mutect2, pindel, varscan2
- SUPT20HL2 | c.367C>A p.P123T | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ZNF574 | c.670del p.Q224Sfs*144 | Frame Shift Del (DEL) | VAF 41/137 reads (30%) | called by mutect2, pindel, varscan2
- ATIC | c.1080A>T p.G360= | Silent (SNP) | VAF 21/75 reads (28%) | catalogued as COSV99377457; called by muse, mutect2, varscan2
- C3orf52 | c.417A>G p.T139= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as COSV99332286; called by muse, mutect2
- C7orf26 | c.1167C>T p.I389= | Silent (SNP) | VAF 25/66 reads (38%) | catalogued as COSV100732836; called by muse, mutect2, varscan2
- CA3 | c.333A>T p.G111= | Silent (SNP) | VAF 36/106 reads (34%) | catalogued as COSV99570538; called by muse, mutect2, varscan2
- CBLN2 | c.96G>A p.L32= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as rs777498376, COSV54052907, COSV99504436; called by mutect2, varscan2
- CC2D2B | c.828T>A p.I276= | Silent (SNP) | VAF 45/106 reads (42%) | catalogued as COSV100729295; called by muse, mutect2, varscan2
- CCDC85A | c.711G>A p.L237= | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as rs971394913, COSV101339374; called by muse, mutect2, varscan2
- CD109 | c.3144T>C p.L1048= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as COSV54657533; called by muse, mutect2, varscan2
- CDH10 | c.555A>T p.T185= | Silent (SNP) | VAF 28/84 reads (33%) | catalogued as COSV100050086; called by muse, mutect2, varscan2
- CHFR | c.807C>T p.N269= (on ENST00000432561 / NM_001161345.1; = p.N228= on NM_018223.2) | Silent (SNP) | VAF 23/107 reads (21%) | catalogued as rs377318460; called by muse, mutect2, varscan2
- CHMP7 | c.1029G>A p.K343= | Silent (SNP) | VAF 12/16 reads (75%) | catalogued as rs1298433211, COSV100500497; called by muse, mutect2, varscan2
- CNTNAP2 | c.1821G>A p.Q607= | Silent (SNP) | VAF 49/89 reads (55%) | catalogued as COSV100662811, COSV62253882; called by muse, mutect2, varscan2
- COL2A1 | c.2316G>A p.E772= | Silent (SNP) | VAF 58/187 reads (31%) | catalogued as COSV100475484; called by muse, mutect2, varscan2
- CSF2RA | c.1017C>T p.G339= | Silent (SNP) | VAF 109/263 reads (41%) | catalogued as COSV100817459; called by muse, mutect2, varscan2
- DIAPH3 | c.1323T>G p.L441= (on ENST00000400324 / NM_001042517.2; = p.L178= on NM_030932.3) | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as COSV99932785; called by muse, mutect2, varscan2
- DIPK1B | c.237C>T p.V79= | Silent (SNP) | VAF 24/55 reads (44%) | catalogued as COSV100765433; called by muse, varscan2
- DIS3L2 | c.1335C>T p.P445= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as COSV99805481; called by muse, mutect2, varscan2
- ERBB3 | c.1992C>G p.L664= | Silent (SNP) | VAF 23/79 reads (29%) | catalogued as COSV57252588; called by muse, mutect2, varscan2
- FCN3 | c.333A>T p.L111= | Silent (SNP) | VAF 31/69 reads (45%) | catalogued as COSV99585231; called by muse, mutect2, varscan2
- FEV | c.303G>A p.L101= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as rs1361066099, COSV99837856; called by muse, mutect2, varscan2
- GABRG1 | c.1032T>A p.V344= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV99777407; called by muse, mutect2, varscan2
- GJD4 | c.366A>G p.R122= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV100397097; called by muse, mutect2, varscan2
- GLI2 | c.1629C>T p.N543= (on ENST00000361492 / NM_001374353.1; = p.N560= on NM_005270.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 23/87 reads (26%) | catalogued as rs746257608, COSV100082353; called by muse, mutect2, varscan2
- GLP2R | c.390A>T p.S130= | Silent (SNP) | VAF 20/74 reads (27%) | catalogued as COSV99301579; called by muse, mutect2, varscan2
- GLP2R | c.1501C>A p.R501= | Silent (SNP) | VAF 29/120 reads (24%) | catalogued as rs146242583, COSV99301581; called by muse, mutect2
- GPR176 | c.1074C>T p.S358= | Silent (SNP) | VAF 37/135 reads (27%) | catalogued as COSV100136966; called by muse, mutect2, varscan2
- GRIK2 | c.1275A>T p.T425= | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as COSV100023195; called by muse, mutect2, varscan2
- GTF3C1 | c.504T>C p.D168= | Silent (SNP) | VAF 23/60 reads (38%) | catalogued as COSV100648964; called by muse, mutect2, varscan2
- HASPIN | c.1656C>T p.R552= | Silent (SNP) | VAF 18/82 reads (22%) | catalogued as COSV99560375; called by muse, mutect2, varscan2
- HIVEP3 | c.1041G>A p.E347= | Silent (SNP) | VAF 43/169 reads (25%) | catalogued as COSV99911483; called by muse, mutect2, varscan2
- HYOU1 | c.1584C>T p.F528= | Silent (SNP) | VAF 34/94 reads (36%) | catalogued as COSV101345541; called by muse, mutect2, varscan2
- HYOU1 | c.1443C>G p.V481= | Silent (SNP) | VAF 24/107 reads (22%) | catalogued as COSV101345542; called by muse, mutect2, varscan2
- KCNA4 | c.720C>T p.R240= | Silent (SNP) | VAF 34/141 reads (24%) | catalogued as rs915875386, COSV100068541; called by muse, mutect2, varscan2
- KCND2 | c.1818C>T p.T606= | Silent (SNP) | VAF 24/42 reads (57%) | catalogued as rs918777775, COSV100473585; called by muse, mutect2, varscan2
- KLC2 | c.1707C>G p.P569= | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as COSV100270565, COSV100270748; called by muse, mutect2, varscan2
- KLHDC7A | c.1227G>T p.P409= | Silent (SNP) | VAF 19/37 reads (51%) | catalogued as COSV101272719; called by muse, mutect2, varscan2
- LRP12 | c.255C>T p.G85= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as rs191888475; called by muse, mutect2, varscan2
- LRP2 | c.9063T>C p.Y3021= | Silent (SNP) | VAF 24/82 reads (29%) | catalogued as COSV99786549; called by muse, mutect2, varscan2
- LVRN | c.900G>T p.T300= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as COSV100773328; called by muse, mutect2, varscan2
- MAGEC1 | c.1827C>T p.L609= | Silent (SNP) | VAF 139/243 reads (57%) | catalogued as COSV99594838; called by muse, mutect2, varscan2
- MED12 | c.5913G>A p.Q1971= | Silent (SNP) | VAF 37/57 reads (65%) | catalogued as COSV100376105; called by muse, mutect2, varscan2
- MEF2C | c.565C>A p.R189= | Silent (SNP) | VAF 72/177 reads (41%) | catalogued as COSV100424590, COSV60937894; called by muse, mutect2, varscan2
- MOGS | c.795C>T p.T265= | Silent (SNP) | VAF 21/193 reads (11%) | catalogued as COSV52027914; called by muse, mutect2, varscan2
- MYBPC1 | c.2037T>C p.F679= (on ENST00000550270 / NM_206820.2; = p.F704= on NM_002465.4) | Silent (SNP) | VAF 16/57 reads (28%) | catalogued as COSV100637751; called by muse, mutect2, varscan2
- MYOCD | c.1491C>G p.L497= | Silent (SNP) | VAF 19/69 reads (28%) | catalogued as COSV100590169; called by muse, mutect2, varscan2
- NAGLU | c.1074G>T p.P358= | Silent (SNP) | VAF 36/156 reads (23%) | catalogued as rs760335984, COSV99863986; called by muse, mutect2, varscan2
- NCKAP5 | c.1851G>T p.L617= | Silent (SNP) | VAF 17/64 reads (27%) | catalogued as COSV100490055, COSV58442519; called by muse, mutect2, varscan2
- NXNL2 | c.48G>C p.A16= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as COSV101018229, COSV65474226; called by muse, mutect2, varscan2
- NXPH1 | c.810G>T p.S270= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV101339573, COSV68313546; called by muse, mutect2
- OLIG3 | c.258G>A p.L86= | Silent (SNP) | VAF 39/122 reads (32%) | catalogued as COSV100880219; called by muse, mutect2, varscan2
- OPTN | c.1548G>A p.E516= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as COSV99537240; called by muse, mutect2, varscan2
- OR2T33 | c.420G>A p.L140= | Silent (SNP) | VAF 34/195 reads (17%) | catalogued as rs773900472, COSV58815496, COSV58816117; called by muse, mutect2, varscan2
- OR5A1 | c.126G>C p.L42= | Silent (SNP) | VAF 34/128 reads (27%) | catalogued as COSV100118259; called by muse, mutect2
- OR5F1 | c.741C>A p.A247= | Silent (SNP) | VAF 22/75 reads (29%) | catalogued as rs758598701, COSV99558387; called by muse, mutect2, varscan2
- OXCT1 | c.645G>T p.A215= | Silent (SNP) | VAF 88/240 reads (37%) | catalogued as rs778133491, COSV52171416, COSV99541731; called by muse, mutect2, varscan2
- PACSIN1 | c.999G>T p.G333= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as COSV99762860; called by muse, mutect2, varscan2
- PCDHB10 | c.1207C>T p.L403= | Silent (SNP) | VAF 20/48 reads (42%) | catalogued as COSV53378331, COSV99503661; called by muse, mutect2, varscan2
- PKHD1 | c.3729G>T p.T1243= | Silent (SNP) | VAF 19/73 reads (26%) | catalogued as COSV100581074; called by muse, mutect2, varscan2
- PLCH1 | c.3198C>A p.T1066= (on ENST00000340059 / NM_001130960.2; = p.T1058= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 60/159 reads (38%) | catalogued as COSV100395602; called by muse, mutect2, varscan2
- POLN | c.543C>T p.A181= | Silent (SNP) | VAF 23/35 reads (66%) | catalogued as rs201658007, COSV101242475; called by muse, mutect2, varscan2
- PPP1CB | c.778C>A p.R260= | Silent (SNP) | VAF 12/53 reads (23%) | catalogued as COSV56090313, COSV99941684; called by muse, mutect2, varscan2
- PRR5-ARHGAP8 | c.1428G>A p.V476= (on ENST00000352766; = p.V397= on NM_181334.5) | Silent (SNP) | VAF 42/255 reads (16%) | catalogued as COSV100423964; called by muse, mutect2, varscan2
- PTPRH | c.708A>G p.P236= | Silent (SNP) | VAF 21/104 reads (20%) | catalogued as COSV99670672; called by muse, mutect2, varscan2
- RAB6B | c.513G>T p.A171= | Silent (SNP) | VAF 30/92 reads (33%) | catalogued as COSV53316019; called by muse, mutect2, varscan2
- RADX | c.2517T>C p.N839= | Silent (SNP) | VAF 40/65 reads (62%) | catalogued as COSV100998746; called by muse, mutect2, varscan2
- RFC4 | c.930C>G p.L310= | Silent (SNP) | VAF 21/70 reads (30%) | catalogued as rs1229092445, COSV99960990; called by muse, mutect2, varscan2
- RHBDL1 | c.1302C>T p.I434= (on ENST00000219551 / NM_001318733.2; = p.I369= on NM_001278720.2) | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as rs759777387, COSV99555380; called by muse, mutect2, varscan2
- RNF17 | c.1608G>A p.V536= | Silent (SNP) | VAF 26/93 reads (28%) | catalogued as COSV55035402; called by muse, mutect2, varscan2
- ROBO4 | c.2088G>T p.R696= | Silent (SNP) | VAF 37/64 reads (58%) | catalogued as COSV100127297; called by muse, mutect2, varscan2
- RTN1 | c.1791C>T p.D597= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as COSV99954655; called by muse, mutect2
- RUSC1 | c.660C>T p.I220= | Silent (SNP) | VAF 13/76 reads (17%) | catalogued as COSV52740527; called by muse, mutect2, varscan2
- SHLD2 | c.2349C>T p.D783= | Silent (SNP) | VAF 60/144 reads (42%) | catalogued as rs1321113549, COSV100078872; called by muse, mutect2, varscan2
- SOX30 | c.792C>G p.L264= | Silent (SNP) | VAF 25/67 reads (37%) | catalogued as COSV53937533, COSV99398151; called by muse, mutect2, varscan2
- SPRYD7 | c.300G>T p.L100= | Silent (SNP) | VAF 19/68 reads (28%) | catalogued as COSV100709803; called by muse, mutect2, varscan2
- SUSD6 | c.99G>T p.L33= | Silent (SNP) | VAF 35/121 reads (29%) | catalogued as COSV100713327; called by muse, mutect2, varscan2
- TEX47 | c.684A>T p.T228= | Silent (SNP) | VAF 30/64 reads (47%) | catalogued as COSV51878933, COSV99787170; called by muse, mutect2, varscan2
- TINAG | c.906A>T p.V302= | Silent (SNP) | VAF 34/132 reads (26%) | catalogued as COSV52515893; called by muse, mutect2, varscan2
- TLR4 | c.660A>T p.P220= (on ENST00000355622 / NM_138554.5; = p.P180= on NM_003266.4) | Silent (SNP) | VAF 7/55 reads (13%) | catalogued as COSV62923976; called by muse, mutect2, varscan2
- TXLNG | c.1551C>T p.S517= | Silent (SNP) | VAF 35/68 reads (51%) | catalogued as COSV100417817; called by muse, mutect2, varscan2
- UBXN4 | c.378G>A p.Q126= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV99738680; called by muse, mutect2, varscan2
- WDR7 | c.3753G>A p.S1251= | Silent (SNP) | VAF 32/118 reads (27%) | catalogued as rs147412167, COSV99588549; called by muse, mutect2, varscan2
- ZBTB7A | c.1584C>T p.D528= | Silent (SNP) | VAF 6/11 reads (55%) | catalogued as rs749890922, COSV100475365; called by muse, varscan2
- ZFYVE26 | c.1467G>T p.L489= | Silent (SNP) | VAF 28/110 reads (25%) | catalogued as COSV100720080; called by muse, mutect2, varscan2
- FABP5P3 | chr7:152446427 T>A | 3'Flank (SNP) | VAF 157/334 reads (47%) | called by muse, mutect2, varscan2
- SNORD115-32 | n.38G>A | RNA (SNP) | VAF 67/243 reads (28%) | catalogued as rs774230186; called by muse, mutect2, varscan2
- SNORD115-8 | n.82C>A | RNA (SNP) | VAF 82/305 reads (27%) | called by muse, mutect2, varscan2
